Somatic mutation profile of tumor specimen MMRF_1625_1_BM_CD138pos (aliquot MMRF_1625_1_BM_CD138pos_T1_KHS5U_K14080) from MMRF case MMRF_1625, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.7 years (18,870 days).
Specimen MMRF_1625_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c79e5730-055f-466d-8d04-623b3eb73a69.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1625_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1625_1_PB_Whole_C2_KHS5U_K14071; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58c217e3-bc26-4dfa-b6bd-71d59fe391fe

The open-access MAF lists 2,531 somatic variants for this specimen: 955 protein-altering or splice-affecting, 342 silent, 1,234 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 813, 3'UTR 632, Intron 354, Silent 342, 5'UTR 120, Nonsense Mutation 98, 5'Flank 46, RNA 42, 3'Flank 39, Splice Region 14, Splice Site 12, Frame Shift Del 5.

Variants (750 of 2,531; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf70 | c.17C>T p.S6L | Missense Mutation (SNP) | VAF 8/86 reads (9%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs757159118, COSV58586480, COSV58587413, COSV58588338; called by mutect2, varscan2
- FBN1 | c.4292G>A p.C1431Y | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1555397540, CM117721; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 95/248 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- MFRP | chr11:119345487 C>G | 5'Flank (SNP) | VAF 14/133 reads (11%) | catalogued as rs786205472, COSV64129202; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs556022544, COSV55116440; called by muse, mutect2, varscan2
- ABCC1 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60691371; called by muse, mutect2, varscan2
- ABCC8 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as rs759663539; called by muse, mutect2, varscan2
- ABLIM2 | c.31C>G p.P11A | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs1265388339; called by muse, mutect2
- ADCY4 | c.2689G>C p.E897Q | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60253365; called by muse, mutect2, varscan2
- ADGRF3 | c.1003G>A p.D335N (on ENST00000311519 / NM_001145168.1; = p.D136N on NM_153835.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.468); catalogued as rs770396714, COSV61049801; called by muse, mutect2, varscan2
- AFF3 | c.1060G>C p.E354Q | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV99067982; called by muse, mutect2, varscan2
- AICDA | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.508); catalogued as rs779232470, COSV57565606; called by muse, mutect2, varscan2
- ALDH6A1 | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV63246329; called by muse, mutect2
- AMN | c.359C>T p.S120F | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as COSV100141543; called by muse, mutect2
- ANLN | c.3280G>C p.E1094Q | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56075557; called by muse, mutect2
- ANO4 | c.1753G>A p.E585K (on ENST00000392977 / NM_001286615.2; = p.E550K on NM_178826.4) | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.559); catalogued as COSV54603881; called by muse, mutect2
- ANO6 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 11/263 reads (4%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV57663254; called by muse, mutect2
- APC2 | c.4543G>A p.D1515N | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs1049821800; called by muse, mutect2
- APOD | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 20/242 reads (8%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as rs753864007; called by muse, mutect2
- AR | c.1462C>T p.Q488* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as CM015295, COSV65953259; called by muse, varscan2
- ARAP2 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as COSV58283400; called by muse, mutect2, varscan2
- ARCN1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 53/201 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV99873861; called by muse, mutect2, varscan2
- ARHGAP25 | c.1424C>T p.S475L (on ENST00000409202 / NM_001007231.3; = p.S467L on NM_014882.3) | Missense Mutation (SNP) | VAF 50/222 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as COSV54903659, COSV54905677; called by muse, mutect2
- ARID3A | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV55045325; called by muse, mutect2
- ARPP21 | c.2098C>T p.Q700* | Nonsense Mutation (SNP) | VAF 9/220 reads (4%) | catalogued as COSV51792529; called by muse, mutect2
- ASCC3 | c.5365G>A p.E1789K | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs1224805509; called by muse, mutect2, varscan2
- ASTN1 | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); catalogued as COSV56061242, COSV56065424, COSV56078519; called by muse, mutect2
- ATM | c.986G>C p.R329T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53745687; called by muse, mutect2, varscan2
- ATM | c.8576C>T p.S2859F | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs786203542, COSV53748072, COSV53784938; ClinVar: uncertain significance; called by muse, mutect2
- ATOH8 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 100/241 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as rs967865255; called by muse, mutect2, varscan2
- ATRIP | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 61/742 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs1205528744; called by muse, mutect2
- AUTS2 | c.1567G>T p.E523* | Nonsense Mutation (SNP) | VAF 74/187 reads (40%) | catalogued as COSV61402560; called by muse, mutect2, varscan2
- AXIN1 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.804); catalogued as rs754764999; called by muse, mutect2, varscan2
- BATF2 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV57251268; called by muse, mutect2
- BCO2 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 90/215 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV63063050; called by muse, mutect2, varscan2
- BEND5 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV65718718; called by muse, mutect2
- BICDL2 | c.662G>C p.R221P | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); catalogued as COSV54155590; called by muse, mutect2, varscan2
- BPNT1 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 43/576 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776487679, COSV59040258; called by muse, mutect2
- BRAF | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.76); catalogued as CM1513641; called by muse, mutect2, varscan2
- BRINP1 | c.555C>G p.I185M | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.995); catalogued as COSV99777445; called by muse, mutect2, varscan2
- BRWD1 | c.2906G>A p.R969Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765233429; called by muse, mutect2, varscan2
- BRWD3 | c.1448C>T p.S483L | Missense Mutation (SNP) | VAF 72/89 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64752759; called by muse, mutect2, varscan2
- C11orf1 | c.432G>A p.M144I | Missense Mutation (SNP) | VAF 51/420 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.294); catalogued as COSV99500117; called by muse, mutect2, varscan2
- C16orf78 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.071); catalogued as rs373806217; called by muse, mutect2, varscan2
- C19orf67 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.97); catalogued as rs898118607; called by muse, mutect2
- C1QTNF2 | c.985G>A p.E329K (on ENST00000393975; = p.E284K on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.853); catalogued as rs768627769, COSV67433300; called by muse, mutect2, varscan2
- C1orf116 | c.1657G>T p.E553* | Nonsense Mutation (SNP) | VAF 55/187 reads (29%) | catalogued as COSV100847995; called by muse, varscan2
- C1orf56 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 24/570 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.17); catalogued as rs1293814129, COSV54849517; called by muse, mutect2
- C6orf136 | c.851C>G p.S284* (on ENST00000376473 / NM_001109938.3; = p.S150* on NM_145029.4) | Nonsense Mutation (SNP) | VAF 10/188 reads (5%) | catalogued as COSV53313604; called by muse, mutect2
- C7orf57 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 10/152 reads (7%) | catalogued as rs1272178511; called by muse, mutect2
- CACNA1A | c.3102-1G>A p.X1034_splice | Splice Site (SNP) | VAF 5/79 reads (6%) | catalogued as COSV64212390; called by muse, mutect2
- CACNA1H | c.6199G>A p.V2067I | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs370883583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADM1 | c.782A>G p.D261G | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.854); catalogued as COSV100522397; called by muse, mutect2, varscan2
- CALHM2 | c.314C>G p.S105C | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV53295258; called by muse, mutect2, varscan2
- CAPN13 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 102/236 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs368104197; called by muse, mutect2, varscan2
- CBX7 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as rs758040396; called by muse, mutect2, varscan2
- CCDC113 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.025); catalogued as rs761425016, COSV54685114; called by muse, mutect2, varscan2
- CCDC168 | c.14134G>A p.E4712K | Missense Mutation (SNP) | VAF 109/255 reads (43%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.979); catalogued as rs1368873433; called by muse, mutect2, varscan2
- CCR10 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as COSV52852781; called by muse, mutect2
- CD177 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 35/318 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs1190877786, COSV65122585; called by muse, mutect2, varscan2
- CD70 | c.342C>G p.I114M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as rs983449250; called by muse, mutect2, varscan2
- CDCP1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.744); catalogued as COSV56104795; called by muse, mutect2
- CDH22 | c.1621G>A p.E541K | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV64838299; called by muse, mutect2
- CEP170 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV60508701; called by muse, mutect2, varscan2
- CES4A | c.452C>G p.S151W | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV58651552; called by muse, mutect2, varscan2
- CFAP300 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as COSV71570937; called by muse, varscan2
- CFHR5 | c.904del p.A302Qfs*2 | Frame Shift Del (DEL) | VAF 100/200 reads (50%) | catalogued as COSV56827808; called by mutect2, pindel, varscan2
- CHST15 | c.296C>G p.S99C | Missense Mutation (SNP) | VAF 24/205 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); catalogued as COSV60561288; called by muse, mutect2, varscan2
- CLCA1 | c.2542G>A p.D848N | Missense Mutation (SNP) | VAF 113/259 reads (44%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.985); catalogued as rs757375165; called by muse, mutect2, varscan2
- CLEC3A | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 47/179 reads (26%) | catalogued as rs1278896970; called by muse, mutect2, varscan2
- CLIC4 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as rs775302953, COSV100978113; called by muse, mutect2, varscan2
- CLIC5 | c.776A>T p.K259M (on ENST00000185206 / NM_001370649.1; = p.K100M on NM_016929.5) | Missense Mutation (SNP) | VAF 83/196 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs775751621; called by muse, mutect2, varscan2
- COL11A2 | c.2069C>G p.P690R (on ENST00000341947 / NM_080680.3; = p.P583R on NM_080679.2) | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs144992893; called by muse, mutect2, varscan2
- COL15A1 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66648542; called by muse, mutect2
- COL3A1 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.69); catalogued as COSV100483664; called by muse, mutect2
- COL9A1 | c.2416G>A p.E806K | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); catalogued as COSV57887979; called by muse, mutect2
- COMMD3-BMI1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as rs1436104637; called by muse, mutect2, varscan2
- COPB2 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 38/184 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV60814224; called by muse, mutect2, varscan2
- CPB1 | c.572G>C p.R191T | Missense Mutation (SNP) | VAF 14/337 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.495); catalogued as COSV51574151; called by muse, mutect2
- CPNE9 | c.1164G>C p.E388D | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.097); catalogued as COSV56068939; called by muse, mutect2, varscan2
- CPPED1 | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 112/288 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1171853317, COSV55498470; called by muse, mutect2, varscan2
- CPSF1 | c.2252C>T p.S751L | Missense Mutation (SNP) | VAF 109/224 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as rs576268637, COSV58232592; called by muse, mutect2, varscan2
- CR2 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 34/220 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs777257410, COSV65506456; called by muse, mutect2, varscan2
- CR2 | c.2915C>T p.S972L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.116); catalogued as rs772806588; called by muse, mutect2, varscan2
- CYLC1 | c.1099C>A p.P367T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs879119832; called by muse, mutect2, varscan2
- CYP4X1 | c.1233G>A p.W411* | Nonsense Mutation (SNP) | VAF 36/203 reads (18%) | catalogued as rs1395240057; called by muse, mutect2, varscan2
- DCHS1 | c.4492C>G p.P1498A | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.031); catalogued as COSV55041031; called by muse, mutect2
- DCST1 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.053); catalogued as COSV99793663; called by muse, mutect2, varscan2
- DENND1C | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs759200988; called by muse, mutect2, varscan2
- DENND4B | c.1952C>G p.S651C | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1456711842; called by muse, mutect2, varscan2
- DENND5A | c.1576C>T p.Q526* | Nonsense Mutation (SNP) | VAF 30/233 reads (13%) | catalogued as rs1554919062; called by muse, mutect2, varscan2
- DGAT1 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV60047748; called by muse, mutect2
- DHTKD1 | c.767C>G p.S256* | Nonsense Mutation (SNP) | VAF 19/247 reads (8%) | catalogued as rs1484737567; called by muse, mutect2
- DHX36 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs1176396180, COSV57675848; called by muse, mutect2, varscan2
- DIAPH2 | c.2495G>A p.R832K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61265821; called by muse, mutect2, varscan2
- DISP1 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as rs760562145, CM166807, COSV52658246; ClinVar: uncertain significance; called by muse, mutect2
- DLG4 | c.878G>A p.R293H (on ENST00000399506 / NM_001321075.3; = p.R336H on NM_001365.4) | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.13); catalogued as rs749422436, COSV100264062; called by muse, mutect2, varscan2
- DLGAP5 | c.2031G>C p.K677N | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV55964978; called by muse, mutect2, varscan2
- DNAH11 | c.7585G>A p.E2529K | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV60942339; called by muse, mutect2, varscan2
- DNAH7 | c.7204C>G p.Q2402E | Missense Mutation (SNP) | VAF 13/257 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100414436, COSV100415991; called by muse, mutect2
- DNAH9 | c.4342G>A p.E1448K | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.314); catalogued as rs367779417; called by muse, varscan2
- DNAH9 | c.4354G>A p.E1452K | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as rs755374372; called by muse, varscan2
- DOCK5 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs772869298, COSV52400213; called by muse, mutect2, varscan2
- DROSHA | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.085); catalogued as rs759529516; called by muse, mutect2, varscan2
- DUSP16 | c.1430C>G p.S477* | Nonsense Mutation (SNP) | VAF 14/198 reads (7%) | catalogued as COSV53807597; called by muse, mutect2
- DUSP22 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV60530035; called by muse, mutect2
- E2F8 | c.2554C>G p.L852V | Missense Mutation (SNP) | VAF 15/259 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.036); catalogued as COSV51465338; called by muse, mutect2
- EDN2 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs1039710418, COSV65423424; called by muse, mutect2
- EIF3A | c.868C>G p.L290V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100974616; called by muse, mutect2, varscan2
- EIF4A1 | c.945G>C p.M315I | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV51510702; called by muse, mutect2
- EIF5B | c.24G>C p.K8N | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as rs752474657; called by muse, mutect2, varscan2
- ENDOD1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 91/219 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs750770456; called by muse, mutect2, varscan2
- EPAS1 | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1558600507; called by muse, mutect2
- EPHA8 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 124/314 reads (39%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.995); catalogued as rs760621090, COSV51268732; called by muse, mutect2, varscan2
- F5 | c.1198G>A p.E400K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs752636369, COSV63123123; called by muse, mutect2, varscan2
- FAM102A | c.979G>A p.D327N (on ENST00000373095 / NM_001035254.3; = p.D185N on NM_203305.2) | Missense Mutation (SNP) | VAF 30/326 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); catalogued as rs1363423018; called by muse, mutect2
- FAM107A | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758002243; called by muse, mutect2
- FAM71B | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.15); catalogued as COSV57228476, COSV57231453; called by muse, mutect2
- FAM76A | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs778742690, COSV50549870; called by muse, mutect2, varscan2
- FAT1 | c.8362G>A p.E2788K | Missense Mutation (SNP) | VAF 105/277 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV101499676; called by muse, mutect2, varscan2
- FAT4 | c.6830G>A p.R2277K | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1037923157; called by muse, mutect2
- FCRL6 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); catalogued as rs148840420; called by muse, mutect2, varscan2
- FER1L5 | c.3256C>G p.R1086G (on ENST00000623019; = p.R1059G on NM_001293083.2) | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1367170372, COSV67606243; called by muse, mutect2
- FER1L6 | c.4009G>A p.E1337K | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV67552560; called by muse, mutect2
- FFAR1 | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 50/430 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.759); catalogued as rs143187042, COSV99322802; called by muse, mutect2, varscan2
- FGFR1 | c.2399C>T p.P800L (on ENST00000447712 / NM_023110.3; = p.P798L on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.45); catalogued as rs377620009, CM1312716; ClinVar: uncertain significance / benign / likely benign; called by mutect2, varscan2
- FLACC1 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 78/167 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1183206073; called by muse, mutect2, varscan2
- FLG | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.068); catalogued as COSV64238094; called by muse, mutect2, varscan2
- FLG2 | c.4233G>C p.Q1411H | Missense Mutation (SNP) | VAF 75/314 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV101165743; called by muse, mutect2, varscan2
- FNDC11 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.412); catalogued as COSV100918806; called by muse, mutect2
- FOLH1 | c.1749G>A p.M583I | Missense Mutation (SNP) | VAF 65/236 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1281611261; called by muse, mutect2, varscan2
- FOXN3 | c.389C>G p.S130C | Missense Mutation (SNP) | VAF 11/142 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1362981389; called by muse, mutect2
- FRMD4B | c.2440G>C p.E814Q | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs1441945720; called by muse, mutect2
- FSIP2 | c.9400G>A p.E3134K | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs1243157746; called by muse, mutect2
- FUBP3 | c.790G>C p.A264P | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV60515124; called by muse, mutect2, varscan2
- FYB2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV100599132, COSV58585849; called by muse, mutect2
- GABRG2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 61/279 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV62722295; called by muse, mutect2, varscan2
- GBA | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 9/177 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as CM119347; called by muse, mutect2
- GBX2 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 31/296 reads (10%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.596); catalogued as rs774692890; called by muse, mutect2, varscan2
- GID4 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); catalogued as COSV52010204; called by muse, mutect2
- GLIS3 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 76/260 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs746828453, COSV60930958; called by muse, mutect2, varscan2
- GLOD4 | c.691G>A p.D231N (on ENST00000301328 / NM_001366247.1; = p.D216N on NM_016080.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.055); catalogued as COSV56755385; called by muse, mutect2, varscan2
- GMEB2 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as COSV99823488; called by muse, mutect2
- GOT1 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 29/187 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs777225854, COSV65147899; called by muse, mutect2, varscan2
- GPD2 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 20/208 reads (10%) | catalogued as rs769907302; called by muse, mutect2
- GRIN2A | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 46/115 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1198247451, COSV58023791; called by muse, mutect2, varscan2
- GRIN2D | c.1734C>T p.L578= | Splice Region (SNP) | VAF 17/192 reads (9%) | catalogued as rs1407595627, COSV54377886; called by muse, mutect2
- GRWD1 | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV99474242; called by muse, mutect2, varscan2
- GSTM1 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59167163; called by muse, mutect2, varscan2
- GSX1 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV57233036; called by muse, mutect2
- GTF3C1 | c.5542G>A p.E1848K | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.1); catalogued as rs750603013, COSV62240609; called by muse, mutect2, varscan2
- H4C4 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV61590892, COSV61591253, COSV61591576; called by muse, mutect2, varscan2
- HAS1 | c.1694G>A p.R565K | Missense Mutation (SNP) | VAF 19/146 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs751148168; called by muse, mutect2, varscan2
- HAS1 | c.1345G>A p.A449T | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1447720912; called by muse, mutect2, varscan2
- HAS1 | c.915C>G p.I305M | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55787425; called by muse, mutect2
- HAUS6 | c.1954C>G p.H652D | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.354); catalogued as COSV100997802; called by muse, mutect2, varscan2
- HIPK1 | c.2726G>A p.R909Q | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.099); catalogued as rs370415621, COSV61245810; called by muse, varscan2
- HMGXB4 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 58/138 reads (42%) | catalogued as COSV53333198, COSV53333992; called by muse, mutect2, varscan2
- HMGXB4 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV53333263; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as rs1362442748; called by muse, mutect2, varscan2
- HOXD8 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV57485960; called by muse, mutect2, varscan2
- HP1BP3 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1557632226; called by muse, mutect2, varscan2
- HSD17B1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV99864617; called by muse, mutect2
- HTR1F | c.267G>C p.W89C | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60390351; called by muse, mutect2, varscan2
- HTRA2 | c.1138C>G p.R380G | Missense Mutation (SNP) | VAF 18/106 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV51206563; called by muse, mutect2, varscan2
- IFRD2 | c.1184C>G p.S395C | Missense Mutation (SNP) | VAF 41/362 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1553709098; called by muse, mutect2, varscan2
- IGF2BP1 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 71/292 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.154); catalogued as rs1024617698, COSV51736242; called by muse, mutect2, varscan2
- IGLL5 | c.287_288del p.C96Lfs*29 | Frame Shift Del (DEL) | VAF 108/270 reads (40%) | catalogued as rs780729302; called by pindel, varscan2
- IKZF5 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 19/259 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1170832742; called by muse, mutect2
- IL17RC | c.1574C>T p.A525V (on ENST00000295981 / NM_153461.4; = p.A439V on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as rs1317174871, COSV55974100; called by muse, mutect2, varscan2
- IL6ST | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as rs764426398, COSV61140798; called by muse, mutect2, varscan2
- INSRR | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 54/135 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs1272070469, COSV100947552; called by muse, mutect2, varscan2
- INTS6L | c.745G>A p.G249R | Missense Mutation (SNP) | VAF 5/103 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs148434267, COSV100878080; called by muse, mutect2
- IQGAP2 | c.1708G>A p.D570N | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs893428345; called by muse, mutect2, varscan2
- IQGAP3 | c.4051G>A p.E1351K | Missense Mutation (SNP) | VAF 115/409 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV63250657; called by muse, mutect2, varscan2
- IRX5 | c.1028C>T p.S343L | Missense Mutation (SNP) | VAF 11/169 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1471911022, COSV58059921; called by muse, mutect2
- ITGAD | c.25C>A p.L9M | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as COSV66758985; called by muse, mutect2
- ITPKC | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 88/329 reads (27%) | catalogued as COSV54574682; called by muse, mutect2, varscan2
- KCP | c.4285G>A p.E1429K (on ENST00000620378; = p.E1553K on NM_001366122.1) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1424379993; called by muse, mutect2, varscan2
- KDM2B | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100997143, COSV65640684; called by muse, mutect2
- KDM4D | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.053); catalogued as COSV100624387; called by muse, mutect2
- KHNYN | c.494C>G p.S165C | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV99249938; called by muse, mutect2, varscan2
- KIAA1328 | c.795G>C p.E265D | Missense Mutation (SNP) | VAF 52/365 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV54447061; called by muse, mutect2, varscan2
- KIAA1549 | c.2749C>T p.P917S | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.374); catalogued as rs1472373360; called by muse, mutect2, varscan2
- KIAA1614 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 13/111 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1237498792, COSV62550604; called by muse, mutect2, varscan2
- KIF24 | c.1378G>C p.D460H | Missense Mutation (SNP) | VAF 40/490 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1300250038; called by muse, mutect2
- KMT2A | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs781933899; called by muse, mutect2, varscan2
- LCORL | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 58/122 reads (48%) | catalogued as rs1190510160; called by muse, mutect2, varscan2
- LILRA4 | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV52494986; called by muse, mutect2, varscan2
- LRP2 | c.4987C>T p.R1663C | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.409); catalogued as rs898681788, COSV55553067, COSV99787664; called by muse, mutect2, varscan2
- LRRC7 | c.2904G>C p.E968D (on ENST00000651989 / NM_001370785.2; = p.E935D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/227 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as COSV50659975; called by muse, mutect2
- LRRTM4 | c.756G>C p.W252C | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69141173; called by muse, mutect2
- LTC4S | c.299C>A p.S100Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1394719200; called by muse, mutect2
- MAP3K14 | c.1943G>A p.G648E | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.129); catalogued as rs761853119; called by muse, mutect2, varscan2
- MAP3K4 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 59/156 reads (38%) | SIFT tolerated (0.92); PolyPhen benign (0.382); catalogued as rs369809586; called by muse, mutect2, varscan2
- MASP2 | c.542C>G p.S181* | Nonsense Mutation (SNP) | VAF 4/74 reads (5%) | catalogued as COSV68897442; called by muse, mutect2
- MASTL | c.284A>G p.H95R | Missense Mutation (SNP) | VAF 80/216 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs764102088; called by muse, mutect2, varscan2
- MC5R | c.796C>T p.Q266* | Nonsense Mutation (SNP) | VAF 11/161 reads (7%) | catalogued as COSV100229201; called by muse, mutect2
- MDGA1 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.342); catalogued as rs1163229019, COSV51799446; called by muse, mutect2, varscan2
- MDGA2 | c.2534G>A p.R845K (on ENST00000399232 / NM_001113498.2; = p.R547K on NM_182830.4) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.121); catalogued as COSV100636475; called by muse, mutect2, varscan2
- MED12 | c.79C>G p.Q27E | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV61336067; called by muse, mutect2, varscan2
- MED12L | c.5683C>T p.L1895F | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated, low confidence (0.7); PolyPhen possibly damaging (0.564); catalogued as rs1239984334; called by muse, mutect2
- MEF2C | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 21/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60941672; called by muse, mutect2
- METTL25 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 54/289 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.023); catalogued as rs775510618; called by muse, mutect2, varscan2
- MGA | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV54958606; called by muse, mutect2, varscan2
- MIB1 | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55092901; called by muse, mutect2
- MIDN | c.1019C>A p.S340* | Nonsense Mutation (SNP) | VAF 73/273 reads (27%) | catalogued as COSV56295698; called by muse, mutect2, varscan2
- MKI67 | c.3346G>A p.E1116K | Missense Mutation (SNP) | VAF 55/107 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs777442806, COSV64074212; called by muse, mutect2, varscan2
- MLXIP | c.390C>G p.F130L | Missense Mutation (SNP) | VAF 39/393 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as rs761246230; called by muse, mutect2
- MOB1B | c.263C>T p.S88L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100511675; called by muse, mutect2, varscan2
- MON1A | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV56562816; called by muse, mutect2, varscan2
- MORC1 | c.909G>C p.L303F | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV51727405; called by muse, mutect2, varscan2
- MORC1 | c.455G>A p.R152K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV51718743, COSV51729005; called by muse, mutect2, varscan2
- MRPL24 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 141/532 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs760632045; called by muse, mutect2, varscan2
- MRS2 | c.347G>A p.R116K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51233824; called by muse, mutect2, varscan2
- MSH3 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.879); catalogued as rs1408201880, COSV99434669; called by muse, mutect2, varscan2
- MSL1 | c.1250C>G p.S417* (on ENST00000398532 / NM_001365919.1; = p.S154* on NM_001012241.2) | Nonsense Mutation (SNP) | VAF 34/404 reads (8%) | catalogued as COSV59899749; called by muse, mutect2
- MTA1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 22/662 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as rs782105615; called by muse, mutect2
- MTMR11 | c.1016C>T p.S339L (on ENST00000439741 / NM_001145862.2; = p.S267L on NM_181873.3) | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54965741; called by muse, mutect2
- MUC16 | c.4999G>C p.E1667Q | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as COSV67448780; called by muse, mutect2
- MUC17 | c.3890C>A p.T1297N | Missense Mutation (SNP) | VAF 128/448 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs777620617, COSV60288910; called by muse, mutect2, varscan2
- MUC17 | c.5717C>T p.S1906L | Missense Mutation (SNP) | VAF 33/485 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs747229251; called by muse, mutect2
- MUC5B | c.14923C>T p.Q4975* | Nonsense Mutation (SNP) | VAF 73/170 reads (43%) | catalogued as COSV101500698; called by muse, mutect2, varscan2
- MXRA5 | c.5788G>A p.A1930T | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs193920874, COSV54230682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO1A | c.1024C>G p.R342G | Missense Mutation (SNP) | VAF 84/178 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55657076; called by muse, mutect2, varscan2
- MYO3A | c.448G>C p.D150H | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56348661; called by muse, mutect2, varscan2
- NAGS | c.1150G>A p.D384N | Missense Mutation (SNP) | VAF 12/246 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as COSV52814352; called by muse, mutect2
- NAP1L3 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.558); catalogued as COSV100220715; called by muse, mutect2, varscan2
- NAV3 | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.035); catalogued as COSV57098927; called by muse, mutect2
- NCOA6 | c.4673C>T p.S1558F | Missense Mutation (SNP) | VAF 162/189 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV62864872; called by muse, mutect2, varscan2
- NECAB3 | c.525-4C>G | Splice Region (SNP) | VAF 74/91 reads (81%) | catalogued as rs1469706765; called by muse, mutect2, varscan2
- NEK10 | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.847); catalogued as rs1478707778; called by muse, mutect2, varscan2
- NEU4 | c.620G>A p.R207H (on ENST00000391969 / NM_001167602.3; = p.R219H on NM_080741.4) | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as rs544178032, COSV100372237; called by muse, mutect2
- NIPSNAP2 | c.279-1G>A p.X93_splice | Splice Site (SNP) | VAF 76/153 reads (50%) | catalogued as rs1437201867; called by muse, mutect2, varscan2
- NOL4 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs776368354, COSV52361324; called by muse, mutect2, varscan2
- NPAT | c.3781G>A p.D1261N | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.167); catalogued as COSV53721703; called by muse, mutect2
- NPHS2 | c.930G>C p.E310D | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV62635226; called by muse, mutect2, varscan2
- NPIPB2 | c.1023G>A p.W341* (on ENST00000399147; = p.W201* on NM_001355514.1) | Nonsense Mutation (SNP) | VAF 12/108 reads (11%) | catalogued as rs757965858; called by muse, varscan2
- NPR3 | c.68C>G p.S23C | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.183); catalogued as rs1003152360; called by muse, mutect2
- NRDE2 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as rs757136441, COSV62962191, COSV62963346; called by muse, mutect2, varscan2
- NRXN1 | c.4064C>T p.S1355L | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as rs1485085622; called by muse, mutect2, varscan2
- NRXN3 | c.3242C>G p.S1081C (on ENST00000335750 / NM_001330195.2; = p.S708C on NM_004796.6) | Missense Mutation (SNP) | VAF 42/161 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as rs1264129006, COSV59724934; called by muse, mutect2, varscan2
- NSD2 | c.2855G>A p.R952K | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1040367399; called by muse, mutect2, varscan2
- NTM | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV66175414; called by muse, mutect2, varscan2
- NWD2 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV58751639; called by muse, mutect2
- ODF2 | c.398C>T p.A133V (on ENST00000434106 / NM_153433.2; = p.A109V on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs754877415, COSV63546467; called by muse, mutect2, varscan2
- OPRPN | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 97/256 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV68193664; called by muse, mutect2, varscan2
- OR10K1 | c.493C>A p.H165N | Missense Mutation (SNP) | VAF 18/499 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV56874545; called by muse, mutect2
- OR6K3 | c.640G>A p.E214K (on ENST00000368146; = p.E198K on NM_001005327.2) | Missense Mutation (SNP) | VAF 14/299 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.05); catalogued as COSV100933829; called by muse, mutect2
- OR6V1 | c.83C>T p.P28L | Missense Mutation (SNP) | VAF 113/221 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as rs377539840; called by muse, mutect2, varscan2
- OTX2 | c.118C>T p.R40W (on ENST00000408990 / NM_172337.3; = p.R48W on NM_021728.4) | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CD051778, COSV59766281; called by muse, mutect2, varscan2
- PALLD | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | catalogued as COSV99825993; called by muse, mutect2
- PAPPA | c.1891C>T p.P631S | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074667; called by muse, mutect2, varscan2
- PAX3 | c.547_549del p.K183del | In Frame Del (DEL) | VAF 78/200 reads (39%) | catalogued as rs763561793; called by pindel, varscan2
- PBRM1 | c.1069G>C p.E357Q | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as COSV56290096, COSV56294098; called by muse, mutect2, varscan2
- PCDH9 | c.3454C>T p.Q1152* (on ENST00000377865 / NM_203487.3; = p.Q1118* on NM_020403.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | catalogued as rs867111477, COSV60572336; called by muse, mutect2
- PCDHAC2 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 121/283 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782783470; called by muse, mutect2, varscan2
- PCDHGA1 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.009); catalogued as rs898742572, COSV65294827; called by muse, mutect2, varscan2
- PCLO | c.10391C>T p.T3464I | Missense Mutation (SNP) | VAF 146/252 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as rs1228974248; called by muse, mutect2, varscan2
- PDCD1 | c.590G>C p.R197P | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV100545427; called by muse, mutect2, varscan2
- PDIA5 | c.1120_1122del p.K374del | In Frame Del (DEL) | VAF 94/157 reads (60%) | catalogued as rs760334360; called by pindel, varscan2
- PHF19 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV65878067; called by muse, mutect2, varscan2
- PHF8 | c.772G>C p.E258Q (on ENST00000357988 / NM_001184896.1; = p.E222Q on NM_015107.3) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV57685433; called by muse, mutect2, varscan2
- PHLPP2 | c.268C>T p.H90Y | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as rs868705427; called by muse, mutect2
- PHRF1 | c.4276C>T p.H1426Y (on ENST00000264555 / NM_001286581.2; = p.H1425Y on NM_020901.4) | Missense Mutation (SNP) | VAF 72/148 reads (49%) | SIFT tolerated (0.64); PolyPhen benign (0.043); catalogued as rs1289145127; called by muse, mutect2, varscan2
- PIEZO2 | c.6858C>G p.F2286L | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs922583652; called by muse, mutect2, varscan2
- PIK3C2G | c.2577C>G p.F859L (on ENST00000676171; = p.F818L on NM_004570.5) | Missense Mutation (SNP) | VAF 75/200 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV99849478; called by muse, mutect2, varscan2
- PLPPR3 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 70/216 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.044); catalogued as rs1235517882, COSV100608323; called by muse, mutect2, varscan2
- POLR2L | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV58990383, COSV58990492; called by muse, mutect2, varscan2
- POLR3A | c.4018G>A p.V1340M | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1402790359; called by muse, mutect2, varscan2
- POU2F3 | c.181C>T p.R61W | Missense Mutation (SNP) | VAF 140/411 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs372543314, COSV52795036; called by muse, mutect2, varscan2
- PPP1R13L | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 9/175 reads (5%) | catalogued as rs1244370662; called by muse, mutect2
- PPP4R3A | c.1561G>A p.E521K (on ENST00000554943 / NM_001366432.1; = p.E508K on NM_001284280.1) | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as COSV61503441; called by muse, mutect2, varscan2
- PRDM7 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as rs753684287; called by muse, mutect2, varscan2
- PRH2 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.486); catalogued as rs764734814, COSV101113342, COSV67171646; called by muse, mutect2
- PRKD1 | c.2734C>T p.L912F | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs1385886918; called by muse, mutect2, varscan2
- PRKDC | c.11725G>A p.A3909T | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772079669, COSV100038154; called by muse, mutect2, varscan2
- PRR14L | c.4803G>C p.L1601F | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV57888068; called by muse, mutect2, varscan2
- PRUNE2 | c.4753G>A p.E1585K | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.655); catalogued as rs1445636162, COSV65041380; called by muse, mutect2, varscan2
- PSMD6 | c.821C>G p.S274* | Nonsense Mutation (SNP) | VAF 16/320 reads (5%) | catalogued as rs1559676711; called by muse, mutect2
- PSME2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as COSV53756447; called by muse, mutect2
- PTPRD | c.1853G>T p.C618F | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.796); catalogued as rs757562644; called by muse, mutect2, varscan2
- PTPRK | c.3823G>A p.E1275K (on ENST00000368215 / NM_001291984.2; = p.E1276K on NM_002844.4) | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.235); catalogued as rs373557186; called by muse, varscan2
- RAB13 | c.421C>T p.R141* | Nonsense Mutation (SNP) | VAF 16/210 reads (8%) | catalogued as rs367690717; called by muse, mutect2
- RABGAP1 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 89/401 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as COSV100438669; called by muse, mutect2, varscan2
- RAD54B | c.889C>T p.R297* | Nonsense Mutation (SNP) | VAF 56/150 reads (37%) | catalogued as rs373973462; called by muse, mutect2, varscan2
- RAP1GAP2 | c.1801C>T p.Q601* | Nonsense Mutation (SNP) | VAF 67/249 reads (27%) | catalogued as COSV54590195; called by muse, mutect2, varscan2
- RASSF1 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.099); catalogued as COSV51604911; called by muse, mutect2, varscan2
- RBBP9 | c.100-1G>C p.X34_splice | Splice Site (SNP) | VAF 13/56 reads (23%) | catalogued as COSV61500267; called by muse, mutect2, varscan2
- RCN2 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58031783; called by muse, mutect2, varscan2
- RDH10 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV53581729; called by muse, mutect2, varscan2
- RESF1 | c.3850G>A p.D1284N | Missense Mutation (SNP) | VAF 11/105 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as rs1445882010, COSV57021415; called by muse, mutect2, varscan2
- RETREG3 | c.397C>T p.R133W | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs758775508, COSV58705320; called by muse, mutect2, varscan2
- RFX5 | c.1012C>T p.R338C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.425); catalogued as rs752592050; called by muse, mutect2, varscan2
- RGL2 | c.1733C>T p.S578F | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV65842268; called by muse, mutect2, varscan2
- RHBDF2 | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 11/202 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57421687; called by muse, mutect2
- RNASEL | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 28/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62376847; called by muse, mutect2
- RNF213 | c.9454G>A p.E3152K | Missense Mutation (SNP) | VAF 114/385 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60394861; called by muse, mutect2, varscan2
- RPGRIP1 | c.2140C>G p.L714V | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs755065072, COSV52855152; called by muse, mutect2
- RPTN | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 349/609 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.129); catalogued as rs955927284; called by muse, mutect2, varscan2
- RRM1 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 45/88 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as rs2584879; called by muse, mutect2, varscan2
- RSL1D1 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs974783081; called by muse, mutect2, varscan2
- RTCB | c.745G>A p.D249N | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs895945236; called by muse, mutect2
- SAFB | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.901); catalogued as rs1231673195; called by muse, mutect2, varscan2
- SALL4 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV53855790; called by muse, mutect2
- SARM1 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV50229371; called by muse, mutect2, varscan2
- SBF1 | c.4596C>G p.F1532L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.121); catalogued as COSV62365156; called by muse, mutect2
- SCN11A | c.57C>G p.F19L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as COSV56569942, COSV56578964; called by muse, mutect2
- SEMA5B | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 75/225 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV52106586; called by muse, mutect2, varscan2
- SEPHS2 | c.549G>C p.M183I | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV101529312; called by muse, mutect2, varscan2
- SETX | c.6676G>C p.D2226H | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs757223841; called by muse, mutect2, varscan2
- SGSM1 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV68509580; called by muse, mutect2, varscan2
- SH3BP4 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs777809932, COSV100749051; called by muse, mutect2
- SH3RF1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 24/428 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1249348574; called by muse, mutect2
- SHTN1 | c.558G>T p.K186N | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.005); catalogued as rs772929190, COSV53380628; called by muse, mutect2, varscan2
- SIGLEC11 | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.663); catalogued as rs771866761, COSV70221874, COSV70222094; called by muse, mutect2, varscan2
- SIGLEC12 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 79/324 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.5); catalogued as COSV52464859; called by muse, mutect2, varscan2
- SIN3A | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 19/121 reads (16%) | catalogued as COSV64583803; called by muse, mutect2, varscan2
- SKIV2L | c.3601C>T p.Q1201* | Nonsense Mutation (SNP) | VAF 29/394 reads (7%) | catalogued as COSV61713368; called by muse, mutect2
- SLC27A2 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV51061391; called by muse, mutect2
- SLC44A4 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 10/191 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs11551744; called by muse, mutect2
- SLC4A3 | c.1979C>G p.S660C | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV56093963; called by muse, mutect2
- SLIT3 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1313460054, COSV100268900; called by muse, mutect2
- SMAD2 | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV50998791; called by muse, mutect2, varscan2
- SMG8 | c.929G>C p.R310T | Missense Mutation (SNP) | VAF 21/325 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV56286001; called by muse, mutect2
- SMG8 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 44/342 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.381); catalogued as COSV56286275, COSV99958977; called by muse, mutect2, varscan2
- SMG9 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV104372740; called by muse, mutect2, varscan2
- SOCS3 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.015); catalogued as rs1359977252; called by muse, mutect2
- SOX11 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.029); catalogued as COSV100431171; called by muse, mutect2, varscan2
- SP3 | c.2060C>G p.S687* | Nonsense Mutation (SNP) | VAF 11/93 reads (12%) | catalogued as COSV59467213; called by muse, mutect2, varscan2
- SP6 | c.149G>C p.G50A | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.011); catalogued as rs1409399681; called by muse, mutect2
- SPATA31D1 | c.3569C>T p.S1190L | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.224); catalogued as rs1353707106, COSV61201934; called by muse, mutect2
- SSRP1 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV53480020; called by muse, mutect2
- SSX2IP | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.309); catalogued as rs777542271, COSV60552486; called by muse, mutect2, varscan2
- STK11 | c.1068C>G p.I356M | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as rs187744790, COSV100481065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STOX2 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 45/231 reads (19%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.223); catalogued as rs756295358; called by muse, mutect2, varscan2
- SULT1C2 | c.848G>A p.R283K | Missense Mutation (SNP) | VAF 135/371 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1450865393; called by muse, mutect2, varscan2
- SUSD5 | c.120C>G p.F40L | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1351528712; called by muse, mutect2, varscan2
- SYK | c.945G>C p.E315D | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs562109939; called by muse, mutect2, varscan2
- SYNE1 | c.5004G>C p.L1668F (on ENST00000367255 / NM_182961.4; = p.L1675F on NM_033071.3) | Missense Mutation (SNP) | VAF 83/213 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as COSV99561063; called by muse, varscan2
- TAC4 | c.240G>C p.R80S | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.01); catalogued as COSV100402839; called by muse, mutect2
- TAF5L | c.387G>C p.Q129H | Missense Mutation (SNP) | VAF 11/216 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99273199; called by muse, mutect2
- TAS2R42 | c.318C>G p.F106L | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.109); catalogued as COSV62084864; called by muse, mutect2
- TBC1D24 | c.1590C>G p.C530W (on ENST00000646147 / NM_001199107.2; = p.C524W on NM_020705.3) | Missense Mutation (SNP) | VAF 20/334 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1060502501, COSV53546135; ClinVar: uncertain significance; called by muse, mutect2
- TBPL1 | c.155G>C p.R52T | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99393995; called by muse, mutect2, varscan2
- TCF4 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61901116; called by muse, mutect2, varscan2
- TDG | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.026); catalogued as rs772013454; called by muse, mutect2, varscan2
- TENM4 | c.3484G>C p.E1162Q | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53645877; called by muse, mutect2, varscan2
- TFCP2L1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.364); catalogued as rs201891610, COSV99748800; called by muse, mutect2, varscan2
- TFEC | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.275); catalogued as COSV55398415; called by muse, mutect2
- TG | c.1837G>C p.E613Q | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.081); catalogued as COSV55096352; called by muse, mutect2, varscan2
- TMCO6 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as rs1248067497; called by muse, mutect2, varscan2
- TMED4 | c.161-3C>T | Splice Region (SNP) | VAF 11/85 reads (13%) | catalogued as rs769055014; called by muse, mutect2, varscan2
- TMED4 | c.159C>T p.I53= | Splice Region (SNP) | VAF 9/133 reads (7%) | catalogued as rs1398988608; called by muse, mutect2
- TMEM132C | c.2443G>C p.D815H | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV59433310; called by muse, mutect2
- TNC | c.4384G>A p.D1462N | Missense Mutation (SNP) | VAF 58/241 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as rs376977516; called by muse, mutect2, varscan2
- TNNT1 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 57/213 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.487); catalogued as CX163964; called by muse, mutect2, varscan2
- TOMM20L | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as rs761657991, COSV62878299; called by muse, mutect2, varscan2
- TRAJ53 | c.18C>A p.S6R | Missense Mutation (SNP) | VAF 13/243 reads (5%) | PolyPhen possibly damaging (0.859); catalogued as rs1196804899; called by muse, mutect2
- TRIM42 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 26/376 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs745861203, COSV53885591; called by muse, mutect2
- TRIP10 | c.1553C>G p.S518* (on ENST00000313244 / NM_001288962.2; = p.S462* on NM_004240.4) | Nonsense Mutation (SNP) | VAF 17/450 reads (4%) | catalogued as COSV55587789; called by muse, mutect2
- TRMO | c.5G>A p.R2H | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.669); catalogued as rs368353816; called by muse, mutect2, varscan2
- TTC34 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.072); catalogued as rs1046342121; called by muse, mutect2, varscan2
- TTYH2 | c.1103G>A p.R368Q | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs146608677; called by muse, mutect2, varscan2
- TUBB6 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.113); catalogued as rs940484159, COSV52314076; called by muse, mutect2, varscan2
- TUBB6 | c.1324G>C p.E442Q | Missense Mutation (SNP) | VAF 28/256 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.039); catalogued as COSV52316840; called by muse, mutect2, varscan2
- TYMP | c.1013C>T p.S338L | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs753259380; called by muse, varscan2
- TYMP | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.01); catalogued as rs1284840530, COSV52689709, COSV99329590; called by muse, mutect2
- UNC5D | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1247811818; called by muse, mutect2, varscan2
- UQCRH | c.142G>T p.E48* | Nonsense Mutation (SNP) | VAF 13/114 reads (11%) | catalogued as COSV61176791; called by muse, mutect2, varscan2
- USPL1 | c.1637C>T p.S546L | Missense Mutation (SNP) | VAF 13/196 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV55000537; called by muse, mutect2
- UTRN | c.1936C>G p.Q646E | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.779); catalogued as COSV62332302; called by muse, mutect2, varscan2
- VCAN | c.2557G>A p.E853K | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as COSV54097528; called by muse, mutect2
- VIT | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV64895098; called by muse, mutect2
- VPS36 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs772410580; called by muse, mutect2, varscan2
- VWA7 | c.1229C>T p.S410L | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV65174075; called by muse, mutect2
- WDR33 | c.1885C>T p.P629S | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs150827665; called by muse, mutect2, varscan2
- WDR53 | c.302C>A p.S101* | Nonsense Mutation (SNP) | VAF 18/440 reads (4%) | catalogued as rs1040110146, COSV60283489; called by muse, mutect2
- XDH | c.2489G>A p.R830H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755184467; called by muse, mutect2, varscan2
- XIRP2 | c.6688C>T p.Q2230* (on ENST00000628543; = p.Q2405* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 14/286 reads (5%) | catalogued as rs1246163894; called by muse, mutect2
- XRN1 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 70/343 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.013); catalogued as COSV53818400; called by muse, mutect2, varscan2
- YAE1 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 19/258 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV56232824; called by muse, mutect2
- ZBED9 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.956); catalogued as COSV101509318; called by muse, mutect2
- ZCWPW1 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as rs534015238, COSV61249722; called by muse, mutect2, varscan2
- ZDHHC23 | c.1217-7C>G | Splice Region (SNP) | VAF 27/391 reads (7%) | catalogued as rs754172889; called by muse, mutect2
- ZDHHC5 | c.2045C>A p.S682* | Nonsense Mutation (SNP) | VAF 64/156 reads (41%) | catalogued as COSV54707155; called by muse, mutect2, varscan2
- ZFP36L2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as rs1488231952, COSV56698979, COSV56699574, COSV99143900; called by muse, mutect2, varscan2
- ZIM3 | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV54142512; called by muse, mutect2
- ZMYM6 | c.589C>G p.Q197E | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs147071748; called by mutect2, varscan2
- ZNF165 | c.702G>C p.K234N | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.538); catalogued as COSV66102307; called by muse, mutect2
- ZNF257 | c.835C>T p.H279Y | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.334); catalogued as COSV71306564; called by muse, mutect2
- ZNF263 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs750738145, COSV54595918, COSV99526759; called by muse, varscan2
- ZNF331 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.023); catalogued as rs1416538144, COSV53479734; called by muse, mutect2, varscan2
- ZNF367 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.073); catalogued as COSV53564781; called by muse, mutect2, varscan2
- ZNF416 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 113/399 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs773825227; called by muse, mutect2, varscan2
- ZNF616 | c.677C>T p.S226L | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.805); catalogued as COSV57510504; called by muse, mutect2, varscan2
- ZNF638 | c.3319C>T p.P1107S | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52481917; called by muse, mutect2, varscan2
- ZNF701 | c.839C>G p.S280C (on ENST00000301093; = p.S214C on NM_018260.3) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as rs145166923, COSV99990996; called by muse, mutect2, varscan2
- ZNF776 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs980479718; called by muse, mutect2
- ZSCAN5C | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.947); catalogued as rs1208196849; called by muse, mutect2
- A2ML1 | c.4327G>A p.E1443K | Missense Mutation (SNP) | VAF 116/262 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- AAK1 | c.7_9del p.K3del | In Frame Del (DEL) | VAF 21/53 reads (40%) | called by pindel, varscan2
- AARS2 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 15/247 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2
- ABCA7 | c.5224C>G p.P1742A | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- ABCB1 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCC12 | c.566G>T p.R189L | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ABCF3 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 17/370 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- ACADM | c.20G>A p.R7Q | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ACD | c.1634G>C p.*545Sext*15 (on ENST00000620338; = p.*456Sext*15 on NM_022914.3) | Nonstop Mutation (SNP) | VAF 91/376 reads (24%) | called by muse, mutect2, varscan2
- ACE | c.2773G>C p.D925H | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ACTA2 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACTA2 | c.602C>G p.S201C | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- ACTB | c.316A>G p.T106A | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ADAMTS14 | c.2188C>G p.L730V | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ADCY10 | c.1998C>G p.I666M | Missense Mutation (SNP) | VAF 94/179 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- ADGRA3 | c.3409C>T p.Q1137* | Nonsense Mutation (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- ADGRE2 | c.1264G>C p.E422Q | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2
- ADGRF1 | c.2009C>G p.S670C | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- ADGRG4 | c.5407G>A p.E1803K | Missense Mutation (SNP) | VAF 126/145 reads (87%) | SIFT deleterious (0.02); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- ADHFE1 | c.155C>A p.S52* | Nonsense Mutation (SNP) | VAF 59/140 reads (42%) | called by muse, mutect2, varscan2
- ADRB1 | c.1109C>G p.S370W | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHNAK2 | c.12815G>A p.G4272E | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- AKAP11 | c.1799G>A p.R600K | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AKAP14 | c.20C>G p.S7* | Nonsense Mutation (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2, varscan2
- ALAS1 | c.1292G>C p.G431A | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2
- ALDH18A1 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.309); called by muse, mutect2
- ALG1 | c.208+3G>T | Splice Region (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2
- ALPK3 | c.2786C>A p.A929D | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); called by muse, mutect2
- ANGPTL6 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.089); called by muse, mutect2
- ANK3 | c.12716C>T p.S4239L (on ENST00000280772 / NM_001320874.2; = p.S863L on NM_001149.3) | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- ANK3 | c.9316G>C p.E3106Q | Missense Mutation (SNP) | VAF 25/260 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ANKRD26 | c.2137G>T p.E713* | Nonsense Mutation (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- ANKRD26 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD50 | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- ANKRD52 | c.2688G>T p.M896I | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- ANKRD6 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ANO2 | c.2073C>G p.I691M (on ENST00000356134 / NM_001278597.3; = p.I695M on NM_001278596.3) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); called by muse, mutect2
- AOC2 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- AOX1 | c.2831G>A p.G944E | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- AP002495.1 | c.208C>G p.Q70E (on ENST00000528511; = p.Q1E on NM_001375848.1) | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.021); called by muse, mutect2
- AP2S1 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.769); called by muse, mutect2
- AP4E1 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- APBB2 | c.1591G>A p.D531N (on ENST00000295974 / NM_001166050.2; = p.D532N on NM_004307.2) | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- APOA1 | c.538G>A p.V180M | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- APOF | c.676C>G p.L226V | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); called by muse, mutect2
- ARAP2 | c.1457C>T p.S486L | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2
- AREL1 | c.1454C>G p.S485* | Nonsense Mutation (SNP) | VAF 13/326 reads (4%) | called by muse, mutect2
- ARHGAP21 | c.4196C>T p.S1399F | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- ARHGAP21 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 11/273 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- ARHGAP28 | c.1267T>C p.S423P (on ENST00000383472 / NM_001366230.1; = p.S264P on NM_001010000.3) | Missense Mutation (SNP) | VAF 28/176 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ARHGAP32 | c.4286C>G p.S1429C (on ENST00000310343 / NM_001378025.1; = p.S1080C on NM_014715.4) | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); called by muse, mutect2
- ARL10 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- ASH2L | c.1182C>G p.I394M | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ASPM | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.187); called by muse, mutect2
- ASPSCR1 | c.636G>C p.L212F | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ATF7IP | c.2566C>T p.Q856* | Nonsense Mutation (SNP) | VAF 28/188 reads (15%) | called by muse, varscan2
- ATG9A | c.34G>C p.E12Q | Missense Mutation (SNP) | VAF 81/232 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.968); called by muse, varscan2
- ATM | c.2125-3_2125-2del p.X709_splice | Splice Site (DEL) | VAF 45/119 reads (38%) | called by mutect2, pindel, varscan2
- ATP13A5 | c.3013T>A p.Y1005N | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ATP2B3 | c.2950G>C p.E984Q | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2
- ATP6V1G3 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATP7A | c.788C>T p.S263L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ATXN2 | c.2840C>A p.S947Y (on ENST00000550104; = p.S787Y on NM_002973.4) | Missense Mutation (SNP) | VAF 17/277 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2
- ATXN3 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.744); called by muse, mutect2
- BAG2 | c.457C>G p.Q153E | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- BAZ2A | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 14/207 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2
- BCAR1 | c.6C>G p.N2K | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMP2K | c.1573C>T p.Q525* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- BNIPL | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- BOD1L1 | c.6088G>C p.E2030Q | Missense Mutation (SNP) | VAF 21/134 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- BTAF1 | c.5025G>C p.L1675F | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- BTNL9 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 98/226 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.188); called by muse, mutect2
- BZW1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/288 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- C17orf49 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 88/350 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- C17orf75 | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 111/372 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- C19orf57 | c.923C>T p.S308F | Missense Mutation (SNP) | VAF 23/328 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.112); called by muse, mutect2
- C1GALT1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- C1orf131 | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- C1orf167 | c.3161G>A p.R1054K | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); called by muse, mutect2
- C1orf226 | c.704G>C p.S235T | Missense Mutation (SNP) | VAF 34/312 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- C2orf16 | c.3239C>A p.S1080* | Nonsense Mutation (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- C2orf81 | c.519G>A p.W173* | Nonsense Mutation (SNP) | VAF 7/125 reads (6%) | called by muse, mutect2
- C3orf62 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 15/267 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2
- CACNA1H | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 75/169 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACYBP | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 175/339 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- CADPS | c.2561C>T p.S854L | Missense Mutation (SNP) | VAF 27/299 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.138); called by muse, mutect2
- CAMK4 | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- CANX | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CARD14 | c.898G>C p.E300Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- CARS2 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- CASP14 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CASP8AP2 | c.5068C>G p.P1690A | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.225); called by muse, mutect2
- CASTOR2 | c.636-1G>C p.X212_splice | Splice Site (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- CATSPERG | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2
- CCDC125 | c.403C>G p.Q135E | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2
- CCDC173 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CCDC185 | c.898C>T p.R300W | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- CCND2 | c.400C>T p.Q134* | Nonsense Mutation (SNP) | VAF 26/62 reads (42%) | called by muse, mutect2, varscan2
- CCNE1 | c.1004C>T p.A335V | Missense Mutation (SNP) | VAF 11/178 reads (6%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.476); called by muse, mutect2
- CCR2 | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 22/418 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2
- CCSER1 | c.2339dup p.N780Kfs*13 | Frame Shift Ins (INS) | VAF 97/329 reads (29%) | called by mutect2, pindel, varscan2
- CD96 | c.964G>A p.E322K (on ENST00000283285 / NM_198196.3; = p.E306K on NM_005816.5) | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- CDC25B | c.805G>A p.D269N (on ENST00000245960 / NM_021873.3; = p.D255N on NM_004358.4) | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDHR5 | c.2386G>T p.D796Y (on ENST00000358353 / NM_001171968.2; = p.D802Y on NM_021924.5) | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDKL1 | c.290G>C p.R97T | Missense Mutation (SNP) | VAF 6/166 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.272); called by muse, mutect2
- CEACAM20 | c.1479C>G p.I493M | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.269); called by muse, mutect2
- CELF1 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, varscan2
- CENPT | c.1606G>C p.E536Q | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- CENPX | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- CEP290 | c.2245C>G p.L749V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CEP70 | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- CEP97 | c.2269G>A p.E757K | Missense Mutation (SNP) | VAF 21/404 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2
- CFAP251 | c.-18G>C | Splice Region (SNP) | VAF 64/337 reads (19%) | called by muse, mutect2, varscan2
- CFAP94 | c.118G>A p.E40K (on ENST00000320267 / NM_001352064.2; = p.E46K on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.531); called by muse, mutect2
- CHIA | c.16C>G p.L6V | Missense Mutation (SNP) | VAF 156/421 reads (37%) | SIFT tolerated (0.3); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CHRDL2 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CHUK | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- CIT | c.4095C>G p.F1365L | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); called by muse, mutect2
- CKAP2 | c.1930G>C p.D644H (on ENST00000378037 / NM_001098525.2; = p.D643H on NM_018204.5) | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- CLEC14A | c.1379C>A p.T460K | Missense Mutation (SNP) | VAF 355/560 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- CNOT1 | c.6304C>G p.L2102V | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- CNOT3 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 23/219 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COL4A3 | c.3243G>C p.K1081N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.425); called by muse, mutect2
- CPD | c.980G>A p.W327* | Nonsense Mutation (SNP) | VAF 129/531 reads (24%) | called by muse, mutect2, varscan2
- CRELD1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 41/327 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CRTC1 | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CRYBB2 | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- CSHL1 | c.471+3G>A | Splice Region (SNP) | VAF 15/151 reads (10%) | called by muse, mutect2, varscan2
- CYP11A1 | c.369C>G p.I123M | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- CYP2C8 | c.846C>G p.F282L | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CYSLTR2 | c.498C>G p.I166M | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2
- DCST1 | c.196C>T p.Q66* | Nonsense Mutation (SNP) | VAF 24/262 reads (9%) | called by muse, mutect2
- DDIAS | c.2528C>T p.S843L | Missense Mutation (SNP) | VAF 36/634 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- DECR1 | c.993G>C p.K331N | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DHDH | c.341G>A p.R114Q | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DHX36 | c.1555T>A p.F519I | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- DICER1 | c.3294G>C p.W1098C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- DIP2C | c.4363C>T p.H1455Y | Missense Mutation (SNP) | VAF 65/144 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- DMXL2 | c.5369G>C p.R1790T | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.269); called by muse, mutect2
- DNAH1 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.012); called by muse, mutect2
- DNAH11 | c.9692G>A p.R3231K | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.065); called by muse, mutect2
- DNAH11 | c.13218G>C p.L4406F | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH12 | c.6892-1G>C p.X2298_splice | Splice Site (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- DNAJC21 | c.1109C>G p.S370C | Missense Mutation (SNP) | VAF 60/138 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- DNAJC7 | c.1448-7C>T | Splice Region (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- DOCK5 | c.3178C>T p.Q1060* | Nonsense Mutation (SNP) | VAF 39/317 reads (12%) | called by muse, mutect2, varscan2
- DPF3 | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 49/193 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DRC1 | c.1384C>G p.L462V | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- DTX4 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 97/290 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DXO | c.813-1G>A p.X271_splice | Splice Site (SNP) | VAF 22/418 reads (5%) | called by muse, mutect2
- EFCAB3 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 24/267 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EFCAB5 | c.2233G>A p.E745K | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.444); called by muse, mutect2
- EFTUD2 | c.94dup p.D32Gfs*3 | Frame Shift Ins (INS) | VAF 27/176 reads (15%) | called by mutect2, pindel, varscan2
- EHBP1 | c.3090G>A p.M1030I | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF2B2 | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- EIF4G2 | c.2368G>A p.E790K | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.7); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- EIF4G2 | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 63/161 reads (39%) | called by muse, mutect2, varscan2
- ELF4 | c.705G>C p.E235D | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- ELL | c.1036C>T p.Q346* | Nonsense Mutation (SNP) | VAF 11/182 reads (6%) | called by muse, mutect2
- ENTR1 | c.848G>C p.R283T (on ENST00000357365 / NM_001039707.2; = p.R260T on NM_006643.4) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- EPN3 | c.1370G>A p.G457E | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.046); called by muse, mutect2
- ESPL1 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 32/388 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); called by muse, mutect2
- ESYT1 | c.2485G>T p.D829Y | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- EVC | c.2017G>C p.E673Q | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EYA3 | c.1558G>C p.E520Q | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- F8 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 54/62 reads (87%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM172A | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 19/326 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.437); called by muse, mutect2
- FAM184B | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2
- FAM186A | c.5600C>A p.S1867Y | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.171); called by muse, mutect2
- FAM205A | c.1036C>G p.Q346E | Missense Mutation (SNP) | VAF 32/470 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2
- FAM221B | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- FAM76A | c.516G>C p.Q172H | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- FAM76B | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- FAM81A | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 64/143 reads (45%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FANCA | c.2656G>A p.E886K | Missense Mutation (SNP) | VAF 13/160 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.388); called by muse, mutect2
- FARS2 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2
- FAT1 | c.10969G>T p.G3657C | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBF1 | c.866G>C p.G289A (on ENST00000586717; = p.G303A on NM_001319193.1) | Missense Mutation (SNP) | VAF 75/104 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBN2 | c.5254G>A p.E1752K | Missense Mutation (SNP) | VAF 77/200 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FGD5 | c.2222G>C p.R741T | Missense Mutation (SNP) | VAF 57/404 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FMNL1 | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 70/162 reads (43%) | called by muse, mutect2, varscan2
- FMO5 | c.1285C>A p.Q429K | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- FNIP1 | c.2860G>A p.D954N | Missense Mutation (SNP) | VAF 25/338 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.167); called by muse, mutect2
- FOXJ3 | c.1258C>G p.P420A | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FRMPD1 | c.52G>C p.E18Q | Missense Mutation (SNP) | VAF 149/665 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FSIP2 | c.4112C>T p.A1371V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FSIP2 | c.10431del p.K3479Nfs*8 | Frame Shift Del (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- FUT8 | c.1619C>G p.S540C (on ENST00000360689 / NM_001371534.1; = p.S377C on NM_004480.4) | Missense Mutation (SNP) | VAF 38/341 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FYN | c.511G>A p.G171S | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- GALNT3 | c.1197G>A p.W399* | Nonsense Mutation (SNP) | VAF 63/175 reads (36%) | called by muse, mutect2, varscan2
- GARRE1 | c.2528C>G p.S843* | Nonsense Mutation (SNP) | VAF 31/240 reads (13%) | called by muse, mutect2, varscan2
- GATM | c.853C>G p.L285V | Missense Mutation (SNP) | VAF 62/169 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GDAP1 | c.218C>T p.S73L | Missense Mutation (SNP) | VAF 41/504 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- GGN | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- GHRHR | c.855C>G p.I285M | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GJA8 | c.1234G>A p.D412N | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.327); called by muse, mutect2
- GJC1 | c.1087C>G p.H363D | Missense Mutation (SNP) | VAF 32/320 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- GLE1 | c.1642C>T p.Q548* | Nonsense Mutation (SNP) | VAF 33/88 reads (38%) | called by muse, mutect2, varscan2
- GLT1D1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- GMPS | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.094); called by muse, mutect2
- GNAS | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 14/240 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.109); called by muse, mutect2
- GOLGA3 | c.1452G>A p.M484I | Missense Mutation (SNP) | VAF 65/150 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GPR161 | c.175C>T p.L59F | Missense Mutation (SNP) | VAF 17/316 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2
- GPSM2 | c.916C>G p.L306V | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2
- GRM7 | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.025); called by muse, mutect2
- GSN | c.1062G>C p.E354D | Missense Mutation (SNP) | VAF 24/196 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GTF3C1 | c.934G>C p.E312Q | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); called by muse, mutect2
- HEATR1 | c.5511G>A p.W1837* | Nonsense Mutation (SNP) | VAF 9/241 reads (4%) | called by muse, mutect2
- HEATR5B | c.2672G>C p.R891T | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.146); called by muse, mutect2
- HELZ | c.2794G>T p.E932* | Nonsense Mutation (SNP) | VAF 213/725 reads (29%) | called by muse, mutect2, varscan2
- HHAT | c.1055T>C p.I352T | Missense Mutation (SNP) | VAF 108/169 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- HIRIP3 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 35/590 reads (6%) | called by muse, mutect2
- HIVEP1 | c.7796C>T p.S2599F | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- HIVEP3 | c.3239C>G p.S1080C | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- HMCN1 | c.3405G>A p.M1135I | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- HOXB1 | c.482C>A p.S161Y | Missense Mutation (SNP) | VAF 51/203 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HOXB4 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 54/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HP1BP3 | c.859C>T p.Q287* | Nonsense Mutation (SNP) | VAF 8/139 reads (6%) | called by muse, mutect2
- HRC | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 103/331 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSD3B2 | c.1006G>C p.D336H | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- HSF5 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); called by muse, mutect2
- HTT | c.8982G>A p.M2994I | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- HUWE1 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 46/49 reads (94%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- IDO1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 55/139 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IFNAR2 | c.1365G>C p.E455D | Missense Mutation (SNP) | VAF 168/494 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IFRD2 | c.1441-4C>G | Splice Region (SNP) | VAF 22/261 reads (8%) | called by muse, mutect2
- IGHV1-46 | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 48/324 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGHV3-49 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- IGKV1-27 | c.180G>T p.Q60H | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- IL27RA | c.1569C>G p.F523L | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- IL6ST | c.1838T>G p.F613C | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- IMP4 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 33/397 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.387); called by muse, mutect2
- INPP4A | c.313C>G p.Q105E | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.87); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- INPPL1 | c.3684C>T p.L1228= | Splice Region (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- INTS6L | c.2509G>T p.E837* | Nonsense Mutation (SNP) | VAF 12/78 reads (15%) | called by muse, mutect2
- INTU | c.1909G>A p.G637R | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- IP6K2 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- IPO5 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.013); called by muse, mutect2
- IRS4 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ITGB1BP2 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.95); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- JAM2 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); called by muse, mutect2
- JMJD7-PLA2G4B | c.2025G>C p.Q675H | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- JPH1 | c.735G>C p.M245I | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KANK3 | c.2501T>C p.L834P | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- KCNA3 | c.838A>G p.S280G | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNA4 | c.1571C>T p.T524I | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNJ9 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KCNK13 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KDM2B | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- KIAA0232 | c.1444G>C p.D482H | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- KIAA1328 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA1549 | c.178_179dup p.D63Qfs*20 | Frame Shift Ins (INS) | VAF 17/33 reads (52%) | called by pindel, varscan2
- KIF22 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KIF3A | c.1555G>C p.E519Q | Missense Mutation (SNP) | VAF 15/177 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.191); called by muse, mutect2
- KLHL2 | c.589C>T p.L197F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- KMT2E | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- KNDC1 | c.2106G>C p.E702D | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- KNG1 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 92/377 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KNTC1 | c.4921C>T p.H1641Y | Missense Mutation (SNP) | VAF 13/139 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- LAMC3 | c.2935G>C p.E979Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- LAMC3 | c.4618G>A p.E1540K | Missense Mutation (SNP) | VAF 48/191 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LAMP2 | c.141G>C p.Q47H | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- LGALS9B | c.626C>G p.S209C | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- LHX2 | c.1007C>G p.S336W | Missense Mutation (SNP) | VAF 82/291 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- LMTK2 | c.644A>G p.E215G | Missense Mutation (SNP) | VAF 55/140 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LONRF3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); called by muse, mutect2
- LOXHD1 | c.3925G>C p.E1309Q | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- LRIT1 | c.1711T>C p.Y571H | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRP12 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 47/767 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.321); called by muse, mutect2
- LRP1B | c.13664C>A p.T4555K | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LRP1B | c.10349T>C p.I3450T | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRC10B | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRC39 | c.250C>T p.Q84* | Nonsense Mutation (SNP) | VAF 90/197 reads (46%) | called by muse, mutect2, varscan2
- LRRC47 | c.1438_1443del p.F480_L481del | In Frame Del (DEL) | VAF 16/85 reads (19%) | called by mutect2, pindel, varscan2
- LRRC63 | c.260C>A p.S87* | Nonsense Mutation (SNP) | VAF 97/243 reads (40%) | called by muse, mutect2, varscan2
- LRRFIP2 | c.394C>G p.H132D | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- LSG1 | c.14G>C p.R5T | Missense Mutation (SNP) | VAF 9/188 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- LTBP4 | c.2078C>G p.S693C (on ENST00000308370 / NM_001042544.1; = p.S656C on NM_003573.2) | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- LY75 | c.2420-1G>C p.X807_splice | Splice Site (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- MACF1 | c.7847C>G p.S2616C | Missense Mutation (SNP) | VAF 102/280 reads (36%) | called by muse, mutect2, varscan2
- MADD | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- MAGOHB | c.311C>T p.S104L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- MALRD1 | c.2767C>T p.Q923* | Nonsense Mutation (SNP) | VAF 85/171 reads (50%) | called by muse, mutect2, varscan2
- MAN1A1 | c.1809G>C p.Q603H | Missense Mutation (SNP) | VAF 18/341 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MAN1C1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 34/658 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- MAPK4 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.02); called by muse, mutect2
- MAPK6 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 21/313 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2
- MAPK8IP1 | c.1721C>T p.S574L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MATN3 | c.485C>G p.S162* | Nonsense Mutation (SNP) | VAF 10/146 reads (7%) | called by muse, mutect2
- MCM2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MDH1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- MED1 | c.3365C>T p.S1122L | Missense Mutation (SNP) | VAF 69/270 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- MED11 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2
- MED24 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 10/276 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); called by muse, mutect2
- MEIOC | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 116/562 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- METTL8 | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- MGAM2 | c.848-1G>C p.X283_splice | Splice Site (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- MGAT2 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MICALL1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MICU3 | c.1459G>C p.D487H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MKKS | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 100/115 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MMP25 | c.628G>C p.D210H | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MMRN1 | c.1195C>G p.Q399E | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2
- MOCOS | c.2218C>G p.L740V | Missense Mutation (SNP) | VAF 144/348 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOSPD2 | c.711C>G p.F237L | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- MPDZ | c.2401G>A p.D801N | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- MRGPRX3 | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- MRPL16 | c.122-1G>A p.X41_splice | Splice Site (SNP) | VAF 5/71 reads (7%) | called by muse, mutect2
- MSH4 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MSMB | c.110-1G>C p.X37_splice | Splice Site (SNP) | VAF 16/186 reads (9%) | called by muse, mutect2
- MTOR | c.5296G>C p.E1766Q | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- MTREX | c.2860G>A p.D954N | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.177); called by muse, mutect2
- MTREX | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTSS1 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.259); called by muse, mutect2
- MTX3 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | called by muse, mutect2, varscan2
- MUC1 | c.3109C>T p.H1037Y (on ENST00000611571 / NM_001371720.1; = p.H250Y on NM_001204285.2) | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MUC19 | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- MUCL3 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYBPC3 | c.3010C>T p.Q1004* | Nonsense Mutation (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- MYBPC3 | c.2741C>G p.S914* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | called by muse, mutect2, varscan2
- MYH1 | c.1037C>T p.S346L | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2
- MYOF | c.4006G>C p.E1336Q | Missense Mutation (SNP) | VAF 30/205 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- NAB1 | c.956C>G p.S319* | Nonsense Mutation (SNP) | VAF 26/67 reads (39%) | called by muse, mutect2, varscan2
- NADSYN1 | c.2120G>C p.*707Sext*26 | Nonstop Mutation (SNP) | VAF 7/106 reads (7%) | called by muse, mutect2
- NAGPA | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 5/86 reads (6%) | PolyPhen benign (0); called by muse, mutect2
- NANP | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAV2 | c.5594C>G p.S1865C (on ENST00000396087 / NM_001244963.2; = p.S1806C on NM_145117.5) | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NCKAP5 | c.1672C>T p.Q558* | Nonsense Mutation (SNP) | VAF 60/125 reads (48%) | called by muse, mutect2, varscan2
- NDUFB4 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.751); called by muse, mutect2
- NDUFC1 | c.177C>G p.I59M | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); called by muse, mutect2
- NEB | c.5757A>T p.Q1919H | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NFYA | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NME8 | c.1208C>T p.P403L | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOA1 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 14/251 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2
- NOA1 | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 22/283 reads (8%) | called by muse, mutect2
- NOTCH2 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2, varscan2
- NPHP4 | c.4189C>T p.Q1397* | Nonsense Mutation (SNP) | VAF 62/167 reads (37%) | called by muse, mutect2, varscan2
- NPR1 | c.2536G>A p.E846K | Missense Mutation (SNP) | VAF 72/243 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NPRL2 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); called by muse, mutect2
- NPTX2 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- NR3C2 | c.952A>G p.N318D | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2
- NR4A3 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 157/633 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- NRIP2 | c.244_251del p.Q82Afs*88 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- NRP2 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- NRXN3 | c.1018G>C p.E340Q | Missense Mutation (SNP) | VAF 9/256 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.08); called by muse, mutect2
- NSMCE3 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NUP37 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 14/439 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- NUTM1 | c.1580C>T p.S527F | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- NUTM2G | c.469C>T p.L157F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- NXF1 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 10/158 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); called by muse, mutect2
1,781 further variants in this file (206 protein-altering or splice-affecting, 342 silent, 1,233 other) are not listed here.
